Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8E0, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8E0-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

- . Ulcerated invasive poorly differentiated adenocarcinoma (intestinal pattern of Laurén's classification).
- . Maximum size of the tumor: 11.5 cm
- . Depth of infiltration: subserosal adipose tissue
- . Angiolymphatic invasion: present
- . Perineural invasion: present
- . Adjacent mucosa: moderate chronic gastritis associated with intestinal metaplasia of complete and incomplete types and foci of glandular epithelial dysplasia of high degree.
- . Surgical margins: absence of neoplastic involvement
- . 20 lymph nodes were dissected from the peri-gastric fat, of which 6 are involved by neoplasia (6/20), with capsular transposition, as follows:
- Lesser curvature: 3/11
- Greater curvature: 3/9

2 - "7 lymph node":

- One lymph node uninvolved by neoplasia (0/1).
- Fragment of pancreatic tissue uninvolved by neoplasia.

3 - "12p lymph node":

- One lymph node uninvolved by neoplasia (0/1).

4 - "11p lymph node":

- One lymph node uninvolved by neoplasia (0/1).

ICD-O-3
Adenocarcinoma, intestinal
Type 8144/3
Site Body & stomach C16.2
Op 11/23/13

Source: NCI Genomic Data Commons file 40539b97-6ec9-4c42-afef-75995388df32 (TCGA-VQ-A8E0.30080B9A-D8A3-42CC-BF33-F03462DC6C63.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).